Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A6RC, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A6RC-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY -

TWENTY LYMPH NODES, NO EVIDENCE OF METASTATIC ADENOCARCINOMA (0/20).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY -

EIGHTEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/18).

PART 3: PROSTATE, RADICAL RETROPUBIC PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE: $4 + 3 = 7$.
- B. THE TUMOR INVOLVES BOTH THE RIGHT AND LEFT LOBES OF THE PROSTATE AND CONSTITUTES APPROXIMATELY 5% OF THE TOTAL PROSTATIC VOLUME EVALUATED.
- C. THE CARCINOMA MEASURES 1.2 CM IN GREATEST NODULAR DIMENSION.
- D. THE CARCINOMA IS CONFINED WITHIN THE CAPSULE OF THE PROSTATE.
- E. ALL INKED MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- F. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
- G. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- H. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
- I. TNM STAGE: T2c N0 MX.
- J. HISTOLOGIC GRADE: G3 (POORLY DIFFERENTIATED).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 4.3
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 3
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 60%
WEIGHT OF PROSTATE: 64.58gm
TUMOR SIZE: Maximum dimension: 1.2 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 38
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

Chcf TAD-3
Adenocarcinoma, acinar
path
Adenocarcinoma NOS
814013
Sute Prostate NOS
814013
CB1.9
JA

Discrepancy	Yes	No
MPAA Discrepancy		☒

Source: NCI Genomic Data Commons file 98ec9c56-5301-4cb7-ac03-a5e65c22a2ae (TCGA-EJ-A6RC.3DB930C6-0B64-4FBF-8BB8-5FA4EBC122CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).